MMRF case MMRF_1637 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/42fef584-82f0-4ea6-b89f-8cbea165f1c0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.3 years (23,473 days); Days to last known disease status: 1,167 days (3.2 years); Days to last follow up: 1,167 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 206 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 209 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 206 days; Days to treatment end: 206 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 207 days; Days to treatment end: 207 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 337 days; Days to treatment end: 460 days (1.3 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 337 days; Days to treatment end: 596 days (1.6 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 597 days (1.6 years); Days to treatment end: 621 days (1.7 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 662 days (1.8 years); Days to treatment end: 719 days (2.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 721 days (2.0 years); Days to treatment end: 838 days (2.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 721 days (2.0 years); Days to treatment end: 1,073 days (2.9 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 838 days (2.3 years); Days to treatment end: 901 days (2.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 906 days (2.5 years); Days to treatment end: 1,073 days (2.9 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 964 days (2.6 years); Days to treatment end: 1,073 days (2.9 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,073 days (2.9 years); Days to treatment end: 1,073 days (2.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 0): M Protein 3.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 137 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.129 mg/dL; Immunoglobulin G 45 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 9.9 g/dL; Glucose 6.22 mmol/L.
- Day 95 (ECOG 0): M Protein 1.81 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 82.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.469 mg/dL; Immunoglobulin G 20.2 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 7.7 g/dL; Glucose 10.7 mmol/L.
- Day 186 (ECOG 0): M Protein 1.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 92.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 20.9 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 14.3 mmol/L.
- Day 257 (ECOG 0): M Protein 0.95 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.045 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 5.45 mmol/L.
- Day 362 (ECOG 0): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.794 mg/dL; Immunoglobulin G 7.19 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.62 g/L; Beta 2 Microglobulin 1.99 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 5.5 g/dL; Glucose 4.4 mmol/L.
- Day 437 (ECOG 0): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.792 mg/dL; Immunoglobulin G 6.27 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.62 µg/mL; Lactate Dehydrogenase 5.15 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 1.3 ×10⁹/L; Absolute Neutrophil 0.5 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 5.56 mmol/L.
- Day 488 (ECOG 0): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.919 mg/dL; Immunoglobulin G 6.91 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.4 g/dL; Glucose 10.7 mmol/L.
- Day 621 (ECOG 0): M Protein 0.47 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 7.92 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 5.9 g/dL; Glucose 8.2 mmol/L.
- Day 719 (ECOG 0): M Protein 0.77 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 86.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.773 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.59 µg/mL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 8.25 mmol/L.
- Day 782 (ECOG 0): M Protein 0.85 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 135 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.108 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 12.3 mmol/L.
- Day 901 (ECOG 0): M Protein 1.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 256 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.161 mg/dL; Immunoglobulin G 19.7 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.12 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 10.1 mmol/L.
- Day 964 (ECOG 0): M Protein 1.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 271 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.114 mg/dL; Immunoglobulin G 20.1 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 1.7 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 32 g/L; Total Protein 6.7 g/dL; Glucose 10.3 mmol/L.
- Day 1,034 (ECOG 0): M Protein 1.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 288 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.127 mg/dL; Immunoglobulin G 17.7 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 13.9 mmol/L.
- Day 1,167 (ECOG 0): M Protein 1.88 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 314 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.134 mg/dL; Immunoglobulin G 23.7 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 7.9 g/dL; Glucose 8.53 mmol/L.

Other clinical attributes
- Day -10: Weight: 100 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Bladder Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1637_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_1637_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
